Gene-level copy-number profile of tumor specimen TCGA-D6-6826-01A from TCGA case TCGA-D6-6826, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.9 years (23,722 days).
Specimen TCGA-D6-6826-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d8a3d8a4-ffc1-4591-8762-de68fe90c34a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-6826-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/798ca605-0ce2-482c-8bf2-238178b8b81f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,987; copy number 2: 24,831; copy number 3: 23,490; copy number 4: 4,924; copy number 5: 3,969; copy number 6: 353; copy number 7: 3; copy number 8: 22; copy number 9: 36; copy number 10: 93; copy number 12: 30; copy number 15: 16; copy number 19: 31; copy number 29: 8; copy number 50: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-6826-01A-11D-1910-01): tumor purity 0.34, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,524,307–22,029,594, 11 genes (within-gene range 0–2): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 248 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,698,238–70,436,584, 25 genes, copy number 9–12: FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 12: AP001271.1.
- chr12:30,086,342–32,107,528, 65 genes, copy number 7–19 (broad region; genes not listed).
- chr12:32,109,076–32,109,602, 1 gene, copy number 8: AC048344.4.
- chr12:64,622,509–71,927,248, 156 genes, copy number 9–50 (within-gene range 3–50) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,987. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
